Surgical pathology report (de-identified scan), TCGA case TCGA-24-1467, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1467-01A (Primary Tumor).

[page 1 of 5]
Patient Name: [REDACTED]

DOB: [REDACTED]

Surgical Pathology Report

Final

Amended?

Surg Path #:

Pat Name:

DOB:

Sex: Female

MRN #:

Service:

Location:

Hospital #:

Date Taken:

Date Rec'd:

Attend Phys:

Final Dx: OVARY, RIGHT, SALPINGO-OOPHORECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA, POORLY DIFFERENTIATED, 25 CM

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA

OVARY, LEFT, SALPINGO-OOPHORECTOMY
- STROMAL HYPERPLASIA AND HYPERTHECOSIS

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA
- EXTENSIVE ADHESIONS

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY
- SQUAMOUS METAPLASIA
- CHRONIC INFLAMMATION

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA
- NO DIRECT MYOMETRIAL INVASION IDENTIFIED
- MULTIPLE SUPERFICIAL FOCI OF PAPILLARY SEROUS ADENOCARCINOMA
LOWER UTERINE SEGMENT ADJACENT TO UPPER ENDOCERVIX

ARE PRESENT IN

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA EXTENSIVELY INVOLVING MYOMETRIAL LYMPHVASCULAR SPACES

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY ADHESIONS
- ADHESIONS

SOFT TISSUE, CUL-DE-SAC, EXCISION
- PAPILLARY SEROUS ADENOCARCINOMA

OMENTUM, OMENTECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA

LYMPH NODES, RIGHT OBTURATOR, EXCISION (FS2, X2)
- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA PRESENT IN 1 OF 3 LYMPH NODES (1/3)

LYMPH NODES, LEFT EXTERNAL ILIAC, EXCISION
- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA PRESENT IN 3 OF 5 LYMPH NODES (3/5)

[page 2 of 5]
Patient Name: [REDACTED]

DOB: [REDACTED]

LYMPH NODES, RIGHT EXTERNAL ILIAC, EXCISION

- METASTATIC ADENOCARCINOMA PRESENT IN 2 OF 3 LYMPH NODES

(2/3)

LYMPH NODES, LEFT OBTURATOR, EXCISION

- NO CARCINOMA PRESENT IN 3 LYMPH NODES (0/3)

LYMPH NODE, PARA-AORTIC, EXCISION

- METASTATIC ADENOCARCINOMA IN 1 LYMPH NODE (1/1)

Primary Path: [REDACTED]

Resident Path: [REDACTED]

Frozen Sect:

FS1: Ovary, right, oophorectomy

- "Poorly differentiated adenocarcinoma of Mullerian origin, areas with endometrioid appearance," by

FS2: Lymph node, right obturator, excision

- "Metastatic adenocarcinoma," by

Gross: The specimens are received in 11 containers of formalin, each labelled with the patient's name. The first is labelled "FS1" and contains four tan, friable, soft tissue fragments measuring from 0.7 x 0.4 x 0.2 cm to 1.6 x 1.2 x 0.4 cm. Labelled FS1. Jar 0.

The second container is labelled "FS2" and contains one slice of tan soft tissue with surrounding adipose tissue measuring 2.7 x 1.7 x 0.2 cm. Labelled FS2. Jar 0.

The third container is labelled "right adnexa - X1" and contains a previously sectioned mass with dimensions and weight consistent with that in the intraoperative consultation (25.0 cm in greatest dimension and 1400 grams). The external surface is white-blue with abundant petechial hemorrhages and fibrinous adhesions. The external surface is grossly consistent with an ovarian capsule. Sections through the mass show cystic and solid areas. The internal cyst wall show abundant tan-brown papillary excrescences and fibrinous adhesions. The solid portion of the tumor is comprised of tan, friable soft tissue with extensive areas of necrosis. Tumor extends to the external surface of the ovarian capsule appearing as tan, friable, papillary excrescences. A fallopian tube is attached to the external surface of the mass and measures 10.0 cm in length. The tumor extends circumferentially around the fallopian tube and focally extends through the fallopian tube wall to obliterate the lumen. The distal portion of the tumor is less involved. The fimbriae and distal fallopian tube are extensively adhered to the ovarian capsule surrounding the tumor mass. Labelled RO1 and RO2, tumor cystic areas with papillary excrescences; RO3 and RO4, tumor solid areas with necrosis; RO5, papillary excrescences on external surface of ovarian capsule; RFT, right fallopian tube involved and uninvolved by tumor. Jar 5.

The fourth container is labelled "uterus, cervix, LSO" and contains a previously bivalved uterus with attached left ovary and left fallopian tube. The uterus size is consistent with that given in the intraoperative consultation (12.0 x 8.0 x 8.0 cm and weighing 298 grams). The cervix measures 4.0 cm in diameter and has an oval external os measuring 0.9 cm in length. The ectocervix is tan with focal petechial hemorrhages. The endocervical canal measures 4.5 cm in length and contains mucinous material. The endometrial cavity measures 4.0 x 7.0 cm. The endometrium is yellow, glistening, and thickened measuring up to 0.3 cm. A tan, friable, poorly demarcated, vaguely papillary endometrial thickening is noted on the anterior endometrial wall

[page 3 of 5]
Patient Name: [REDACTED]

DOB: [REDACTED]

near the right cornu. Similar less-pronounced, poorly demarcated, tan, friable endometrial thickenings are also noted on the posterior endometrial wall near the left cornu and in the lower uterine segment. These areas measure 1.0 x 0.4 cm and 2.0 x 0.8 cm, respectively. These lesions do not grossly appear to infiltrate into the underlying myometrium. The myometrium measures 3.4 cm in thickness and is slightly soft and spongy. Several vaguely nodular areas with slit-like spaces are identified, grossly consistent with adenomyosis. Two well-demarcated, intramural, white, firm nodules are noted in the anterior wall measuring 0.2 and 0.8 cm in maximal dimension. The nodules are grossly consistent with leiomyomas and showed no areas of hemorrhage or necrosis. The uterine serosa is tan-brown with abundant hemorrhage and adherent fibrinous material. No mass lesions are identified. The attached left ovary measures 3.0 x 1.7 x 2.0 cm and shows a cerebriform, tan, yellow external surface with diffuse petechial hemorrhages and focally adherent fibrinous material. The ovarian parenchyma is tan-white with well-demarcated, white areas, some showing central hemorrhage, grossly consistent with corpora albicantia. The attached left fallopian tube is tortuous measuring approximately 6.5 cm in length. Tan, papillary, friable excrescences are noted on the serosal surface 2.5 cm from the distal end. The papillary excrescences form a vague nodule measuring 1.5 x 1.5 cm. The fallopian tube underlying this area is dilated to a diameter of 0.8 cm and contains tan, papillary excrescences similar to that of the overlying serosal tumor. The fallopian tube proximal and distal to this region is grossly unremarkable measuring 0.4 cm in average diameter. Labelled EM1 and EM2, anterior endomyometrium with endometrial lesion and presumed adenomyosis (EM1A and EM1B represent a bisected section); EC1, anterior lower uterine segment and endocervix; C1, anterior cervix (EM1 and EM2, EC1 and C1 represent contiguous sections); EM3 and EM4, posterior endomyometrium with endometrial lesions (EM3A and EM3B and EM4A and EM4B represent bisected sections); EC2, posterior lower uterine segment and endocervix; C2, posterior cervix (EM3 and EM4, EC2 and C2 represent contiguous sections); EM5, anterior endomyometrium with endometrial lesion; M, anterior endomyometrium with leiomyomas; EC3, posterior lower uterine segment and endocervix with endometrial lesion; LFT, left fallopian tube involved and uninvolved by tumor; LO, left ovary including serosal adhesions. Jar 4.

The fifth container is labelled "omentum" and contains a fragment of fibroadipose tissue grossly consistent with omentum measuring 30.0 x 21.0 x 2.0 cm. Multiple (greater than five) tan, firm nodules are identified within the adipose tissue measuring from 0.2 to 1.0 cm in maximum dimension. The nodules are grossly consistent with metastatic disease. Labelled OM1 and OM2, nodules. Jar 4.

The sixth container is labelled "cul de sac nodule" and contains a single, tan, multinodular fragment measuring 0.8 x 0.5 x 0.5 cm. Bisected. Labelled A. Jar 0.

The seventh container is labelled "R obturator LN, X2." It contains multiple fibroadipose tissue fragments measuring 7.5 x 5.0 x 2.5 cm in aggregate. A tan-white, multinodular, poorly demarcated, 2.5 x 3.0 x 2.5 cm mass is noted within the adipose tissue, grossly consistent with metastatic disease. Lymphoid tissue is focally noted around the mass. Two other lymph nodes measuring 1.5 and 2.0 cm in maximal dimension are also identified and show extensive replacement by fibroadipose tissue but no focal

lesions grossly suspicious for metastatic disease. Labelled X2A, nodule with surrounding lymphoid tissue; X2B, additional lymph nodes. Jar 3.

The eighth container is labelled "L ext iliac LN" and contains an irregular fragment of fibroadipose tissue measuring 9.0 x 6.0 x 2.5 cm. Five lymph nodes are identified measuring

[page 4 of 5]
Patient Name: [REDACTED]

DOB: [REDACTED]

[REDACTED]
[REDACTED]

from 1.0 to 3.5 cm in maximal dimension. Two of the lymph nodes are nearly totally replaced by tan-brown, necrotic tissue grossly consistent with metastatic disease. A third lymph node shows a 0.5 cm, white-tan, subcapsular nodule. The remaining two lymph nodes show no evidence of metastatic disease. No definitive extracapsular extension is identified grossly. Labelled B1 and B2, lymph nodes with metastatic disease; B3, uninvolved lymph nodes (each lymphoid fragment represents an individual node). Jar 3.

The ninth container is labelled "R ext iliac LN" and contains multiple irregular fragments of fibroadipose tissue measuring 9.5 x 8.0 x 2.5 cm in aggregate. Three lymph nodes are identified measuring from 1.5 to 4.0 cm in maximal dimension. The two smaller lymph nodes show subcapsular, white, firm nodules grossly consistent with metastatic disease. The larger lymph node shows central white, poorly demarcated, soft areas grossly consistent with fat necrosis but no gross evidence of metastatic disease. No extracapsular extension is grossly identified. Labelled C1, two smaller nodes; C2A and C2B, largest node, bisected. Jar 3.

The tenth container is labelled "L obturator LN" and contains a single irregular fragment of fibroadipose tissue, measuring 5.0 x 3.8 x 2.5 cm. Three lymph nodes are identified measuring from 1.5 to 4.0 cm in maximal dimension. No focal lesions grossly suspicious for metastatic disease are identified. Labelled D1, two smaller lymph nodes; D2A and D2B, one larger lymph node bisected. Jar 1.

The eleventh container is labelled "para aortic LN" and contains a single irregular fragment of fibroadipose tissue measuring 5.0 x 3.5 x 2.0 cm. It contains a single lymph node measuring 4.5 cm in maximal dimension. Multiple tan-white, firm subcapsular nodules are noted, grossly consistent with metastatic disease. Labelled E1A and E1B, lymph node bisected. Jar 1.)

Comment: Papillary serous adenocarcinoma extensively involves the 25 cm right ovary and fallopian tube. The left fallopian tube contains a nodule of adenocarcinoma which invades through the fallopian tube wall to invade the serosal surface. Areas of fallopian tube epithelium adjacent to this nodule show focal in situ carcinoma. The endometrium exhibits several apparently discrete foci of morphologically identical superficial papillary serous adenocarcinoma without direct myometrial invasion but with extensive lymphovascular space invasion. Superficial foci of papillary serous adenocarcinoma are present in the lower uterine segment; one is present adjacent to high endocervix. Papillary serous adenocarcinoma also involves the cul-de-sac biopsy, the omentum (five small nodules measuring 1 cm in greatest dimension), one of three right obturator lymph nodes, three of five left external iliac lymph nodes, two of three right external iliac lymph nodes, and one of one para-aortic lymph nodes. Three left obturator lymph nodes are free of carcinoma.

In cases, such as this one, where morphologically identical papillary serous carcinoma is present in multiple sites it is

difficult to determine which site is the primary one or whether there are multiple primary sites. The extensive involvement of one ovary, a relatively discrete lesion in the fallopian tube with a focal area of adjacent in situ carcinoma, and multiple foci in the endometrium with no myometrial invasion suggest synchronous primary sites. The presence of extensive lymphovascular space invasion in the myometrium, however, could provide a mechanism for spread of an endometrial primary.

History: The patient is a year old woman with a right adnexal mass and an enlarged uterus. Operative procedure: Examination under anesthesia, exploratory laparotomy, total abdominal hysterectomy, bilateral salpingo-oophorectomy, lymph node dissection, and omentectomy.

[page 5 of 5]
Patient Name: [REDACTED]

DOB: [REDACTED]

An intraoperative non-microscopic consultation was obtained and interpreted as: "#1: Picked-up from operating room a right adnexal mass (1400 grams) measuring 25.0 cm in maximal dimension with attached 10.0 cm fallopian tube. The mass had ruptured intraoperatively, but capsule otherwise smooth. Sectioned to show papillary cystic, partially solid mass. Solid portion is soft, pink and fleshy. Frozen as FS1.

#2: Picked-up from operating room uterus and left adnexa (298 grams), uterus measures 12.0 x 8.0 x 8.0 cm. Bivalved to show slightly thickened, yellow, glistening endometrium and a fleshier area around right cornu on anterior wall. Nodular mass at left adnexa - sectioned to show extruding tumor," by.

Date Last Men:
Contraceptive:
Prev Atypical:

Mens. Status:
Other Horm:

Source: NCI Genomic Data Commons file d31562e8-6606-4158-adf1-fee93544c22c (TCGA-24-1467.6949EFBE-C2EA-4767-B194-2343254F2752.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).